CCDI case PBBTRP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/669c1d4a-4311-4738-a466-a37a7cae294e

Demographics
Sex at birth: male; Race: american indian or alaska native; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 5.9 years (2,137 days).

Biospecimens (3 samples)
- Sample 0DI3IR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI3JP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DI5H4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
